Gene-level copy-number profile of tumor specimen ALCH-B284-TTP1-A from ALCHEMIST case ALCH-B284, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.4 years (19,497 days).
Specimen ALCH-B284-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7baf5039-0249-4aa5-a134-ae0d4c61ead9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B284-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/95654513-f412-456a-9211-40018e471349

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 13,652; copy number 2: 41,332; copy number 3: 3,051; copy number 4: 105; copy number 5: 18; copy number 6: 48; copy number 7: 67; copy number 8: 31; copy number 10: 51; copy number 11: 38.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:39,788,967–39,797,911, 2 genes (within-gene range 0–2): AC004987.3, CICP22.
- chr10:67,874,332–67,874,911, 1 gene: RPL12P8.
- chr16:81,022,316–81,096,284, 1 gene (within-gene range 0–1): AC092718.8.
- chr16:81,053,497–81,220,370, 9 genes (within-gene range 0–1): C16orf46, AC092718.3, AC092718.5, AC092718.6, AC092718.1, GCSH, PKD1L2, RNU6-1191P, AC092718.9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 174 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,252,006–3,181,487, 40 genes, copy number 6: AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377.
- chr5:5,390,096–5,422,116, 1 gene, copy number 6 (within-gene range 3–6): AC091978.1.
- chr5:5,420,664–6,030,841, 3 genes, copy number 6: ICE1, AC010266.2, AC010266.1.
- chr5:14,581,792–16,617,058, 31 genes, copy number 7: OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622, RETREG1.
- chr5:16,617,225–16,623,095, 2 genes, copy number 7: AC022113.1, Y_RNA.
- chr5:35,852,695–40,798,374, 79 genes, copy number 7–11 (within-gene range 1–11) (broad region; genes not listed).
- chr7:37,032–294,422, 11 genes, copy number 5: AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3.
- chr14:36,677,921–37,187,314, 7 genes, copy number 5 (within-gene range 4–5): SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P.

Autosomal genes at a single copy (total copy number 1): 12,873. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
